Surgical pathology report (de-identified scan), TCGA case TCGA-QQ-A5VA, project TCGA-SARC (Sarcoma), tissue source site Roswell Park, specimen TCGA-QQ-A5VA-01A (Primary Tumor).

[page 1 of 2]
TSS DeID:
Surgery Date:

FINAL DIAGNOSIS:

1. OMENTUM, partial omentectomy: LIPOSARCOMA, pleomorphic type (see note)
2. PELVIC mass, biopsy: LIPOSARCOMA, pleomorphic type (see note)
3. Tumor from 4th portion of DUODENUM, excision: LIPOSARCOMA, pleomorphic type, involving duodenal wall (see note)
4. SMALL BOWEL with tumor, resection: LIPOSARCOMA, pleomorphic type, involving jejunal wall; margin of resection, negative for tumor
5. PERIRECTAL serosal nodule, excision: LIPOSARCOMA, pleomorphic type (see note)

DIAGNOSIS COMMENT:

NOTE: This patient has a known history of high grade liposarcoma, mixed round and pleomorphic type with focal well differentiated areas, involving small and large bowel, omentum, mesenteries, spleen, pancreas and left kidney. See also

FROZEN SECTION DIAGNOSIS:

FS#2 PELVIC MASS - Sarcoma

Frozen section diagnosis by Dr.. Called to Dr..

GROSS DESCRIPTION:

1. OMENTUM:

Received in formalin bottle labelled with patient's name, and labelled, "#1, omentum" is a yellow-tan, hemorrhagic portion of omentum, measuring in overall dimension, 25.0x11.0x3.0 cm. There are multiple firm white nodules studding the entire portion of the omentum and ranging in size from the largest, 5.0x4.0x2.5 cm. to 1.0 cm. in greatest dimension. Representative sections are taken and submitted in cassettes labelled, "1A" through "1C."

2. FS#2 PELVIC MASS:

Received are two fragments of yellow-white, firm tissue measuring 0.8 and 1.1 cm. in greatest dimension, respectively. Both are submitted in toto as "FS2."

3. TUMOR FROM 4TH PORTION OF DUODENUM:

Received in formalin bottle labelled with patient's name, and labelled, "#3, tumor from 4th portion of duodenum" is brown-tan, white, firm, lobulated tumor mass measuring 12.0x6.0x5.0 cm. in greatest dimension. On cut section, small portion of duodenum in the center of the lobulated tumor measures 4.0x3.0x0.5 cm. The mucosal surface appears

path ICD-O-3
Liposarcoma, pleomorphic 8854/3
GCF Liposarcoma, dedifferentiated 8858/3
Site: path Specified parts of peritoneum
C48.1
GCF Retroperitoneum C48.0
QW #1/2/13

[page 2 of 2]
grossly normal. Serosal surface is attached to the tumor mass, but grossly the tumor does not appear to penetrate the mucosa of the duodenum. The cut surface of the tumor has a firm white-yellow, gritty appearance grossly. Representative sections are taken and submitted in cassettes labelled, "3A" through "3C."

4. SMALL BOWEL WITH TUMOR:

Received in formalin bottle labelled with patient's name, and labelled, "#4, small bowel with tumor" is a portion of small bowel with attached tumor nodule, measuring 51.0 cm. in length by 6.0x3.0 cm. Tumor mass measures 9.0x8.0x3.5 cm. Mucosal surface appears grossly normal. The tumor is attached to the serosal surface. Grossly, it does appear to penetrate through the mucosa of the small bowel. One portion of the small bowel has an old, well-healed anastomotic site. Representative sections are taken as follows:

T1 and T2: small bowel adherent to tumor

DM: distal margin

PM: proximal margin

SM1 and SM2: random sections of small bowel

AN: anastomotic site

5. PERI RECTAL SEROSAL NODULE:

Received in formalin bottle labelled with patient's name, and labelled, "#5, peri rectal serosal nodule" are multiple white-tan yellow fragments of fibroadipose tissue and tumor nodule. The fragments of fibroadipose tissue measure 5.0 cm. in aggregate. The tumor nodule measures 4.5x3.8x2.2 cm. On cut section, tumor nodule is firm, white and yellow. Representative section is taken and submitted as Cassette #5.

Source: NCI Genomic Data Commons file e7eb38ea-a4c8-45e7-8346-c18f699ecc90 (TCGA-QQ-A5VA.739CDA59-8246-41EE-947F-521CD5270776.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).